Somatic mutation profile of tumor specimen 1105223 (aliquot 7316UP-534-1105223) from CPTAC case C287328, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105223: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4e7a4ed-74c4-4b16-b1c4-e9ca600fdb51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105211 (Blood Derived Normal), aliquot 7316UP-534-1105211; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd789478-908d-4b64-887e-d03dcfe6acc7

The open-access MAF lists 52 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, Nonsense Mutation 2, Intron 2, RNA 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD62 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs905911647, COSV58409888; called by muse, mutect2, varscan2
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2, varscan2
- ARHGAP33 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99137504; called by muse, mutect2
- AVPR1A | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs762174402; called by muse, mutect2
- BCL6B | c.125del p.L42Rfs*71 | Frame Shift Del (DEL) | VAF 77/226 reads (34%) | catalogued as rs1270114003; called by mutect2, pindel, varscan2
- COQ8A | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.316); catalogued as rs1246023405; called by muse, mutect2
- DMRT3 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as rs780364024, COSV51905556; called by muse, mutect2
- F2RL3 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50185415, COSV50187057; called by muse, mutect2, varscan2
- FRG2C | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 100/646 reads (15%) | catalogued as rs1392451749; called by muse, mutect2
- HPGDS | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148462970; called by muse, mutect2, varscan2
- LRCH1 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs941415221; called by muse, mutect2, varscan2
- MAPK15 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782239626, COSV100567821; called by muse, mutect2, varscan2
- MYOCD | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58497340; called by muse, mutect2
- NLRP5 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774293395, COSV66767639; called by muse, mutect2, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, mutect2, varscan2
- PCLO | c.7616C>T p.T2539I | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs1474091537; called by muse, mutect2
- POTEE | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 184/476 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as rs766185047; called by muse, mutect2, varscan2
- PRR23C | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1277613821; called by muse, mutect2, varscan2
- RAPGEF6 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs550513672; called by muse, mutect2, varscan2
- TMEM132C | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as rs372279119, COSV59415924; called by muse, mutect2, varscan2
- TTN | c.42628G>A p.V14210I (on ENST00000591111; = p.V6786I on NM_003319.4) | Missense Mutation (SNP) | VAF 17/328 reads (5%) | PolyPhen benign (0.006); catalogued as rs558671515, COSV59864901; called by muse, mutect2
- ZNF469 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 121/247 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as rs761098712; called by muse, mutect2, varscan2
- CEP41 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CTAGE4 | c.2277G>C p.R759S | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); called by mutect2, varscan2
- FHDC1 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO3B | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 175/397 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTOP3 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2
- PSG7 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PTGS2 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- SPAM1 | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP34 | c.2374T>C p.F792L | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- AKAP9 | c.573G>A p.Q191= | Silent (SNP) | VAF 73/399 reads (18%) | catalogued as rs1193980374, COSV100663516; called by muse, mutect2, varscan2
- CCN4 | c.489G>A p.P163= | Silent (SNP) | VAF 165/354 reads (47%) | catalogued as rs368562535; called by muse, mutect2, varscan2
- CYTH3 | c.549C>G p.V183= | Silent (SNP) | VAF 98/392 reads (25%) | called by muse, mutect2, varscan2
- GRAMD1B | c.555G>A p.S185= | Silent (SNP) | VAF 69/135 reads (51%) | catalogued as rs373203630; called by muse, mutect2, varscan2
- IGLC7 | c.141C>T p.S47= | Silent (SNP) | VAF 308/697 reads (44%) | called by muse, varscan2
- IRX2 | c.501C>T p.N167= | Silent (SNP) | VAF 168/468 reads (36%) | catalogued as rs751790146, COSV57411359; called by muse, mutect2, varscan2
- LY9 | c.996C>T p.A332= | Silent (SNP) | VAF 71/190 reads (37%) | catalogued as rs763617259, COSV54439199; called by muse, mutect2, varscan2
- MAGEA6 | c.522C>T p.H174= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as rs1556826517, COSV61448746, COSV61448773; called by muse, mutect2, varscan2
- OR10A4 | c.372C>T p.Y124= | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as rs141771017; called by muse, mutect2, varscan2
- OR4C15 | c.681C>A p.I227= (on ENST00000314644; = p.I173= on NM_001001920.2) | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV100116199, COSV58951738; called by muse, mutect2
- OR9A4 | c.654C>T p.N218= | Silent (SNP) | VAF 75/428 reads (18%) | catalogued as rs782497009, COSV71885195; called by muse, mutect2, varscan2
- PARP12 | c.2098C>A p.R700= | Silent (SNP) | VAF 110/627 reads (18%) | catalogued as rs140064898; called by muse, mutect2
- PAX4 | c.489G>T p.R163= | Silent (SNP) | VAF 139/524 reads (27%) | catalogued as COSV58388457; called by muse, mutect2, varscan2
- RFNG | c.846G>T p.G282= | Silent (SNP) | VAF 70/142 reads (49%) | called by muse, mutect2, varscan2
- RRAD | c.429C>T p.Y143= | Silent (SNP) | VAF 15/248 reads (6%) | catalogued as rs745613040, COSV55336179; called by muse, mutect2
- ZNF24 | c.501T>A p.S167= | Silent (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- ABCC13 | n.4036C>G | RNA (SNP) | VAF 72/150 reads (48%) | catalogued as rs913239027; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1484A>T | Intron (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812238 del GG | 3'Flank (DEL) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- LINC02691 | n.1390C>T | RNA (SNP) | VAF 73/169 reads (43%) | catalogued as rs375399370; called by muse, mutect2, varscan2
- MCF2L2 | c.1862+3831_1862+3834del | Intron (DEL) | VAF 16/38 reads (42%) | catalogued as rs778247162; called by pindel, varscan2
